Gene-level copy-number profile of tumor specimen TCGA-DM-A1HA-01A from TCGA case TCGA-DM-A1HA, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DM-A1HA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.a9a096d8-57eb-408c-b1cc-fe8894d02634.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A1HA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c58a187-64d5-4bfb-a862-7a725181772c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 14,676; copy number 2: 39,011; copy number 3: 4,968; copy number 4: 1,133.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A1HA-01A-11D-A151-01): tumor purity 0.93, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:115,358,498–116,060,891, 5 genes: AL606845.1, LINC02534, FRK, AL357141.1, TPI1P3.
- chr6:116,118,909–116,158,747, 2 genes: COL10A1, NIP7P3.
- chr22:23,536,881–23,638,941, 8 genes: PCAT14, AP000345.1, IGLL1, AP000345.2, AP000346.4, DRICH1, AP000346.3, AP000346.1.
- chr22:23,638,492–23,653,334, 2 genes: AP000346.2, ASLP1.
- chr22:23,738,682–23,895,223, 12 genes (within-gene range 0–1): ZNF70, VPREB3, C22orf15, CHCHD10, MMP11, SMARCB1, DERL3, AP000350.5, SLC2A11, AP000350.4, AP000350.8, RN7SL268P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,279. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
